Gene-level copy-number profile of specimen HCM-BROD-0038-C41-85A from HCMI case HCM-BROD-0038-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 16.2 years (5,911 days).
Specimen HCM-BROD-0038-C41-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15c9fdeb-da5d-4cad-932c-e88be02f14be.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0038-C41-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/7b81d856-fac2-4786-befc-97a0ec78d5a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 311; copy number 1: 5,988; copy number 2: 40,449; copy number 3: 7,804; copy number 4: 2,569; copy number 5: 646; copy number 6: 658; copy number 7: 103; copy number 8: 117; copy number 9: 252; copy number 10: 11.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:111,091,006–111,125,454, 1 gene (within-gene range 0–2): LRRN3.
- chr7:147,080,934–147,378,121, 4 genes (within-gene range 0–2): CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr13:110,123,208–110,307,157, 3 genes (within-gene range 0–2): AL390755.2, COL4A1, AL161773.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,787 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,643,440–59,926,773, 18 genes, copy number 5: MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2.
- chr1:69,055,838–98,760,500, 414 genes, copy number 5–8 (within-gene range 5–9) (broad region; genes not listed).
- chr1:99,263,953–102,389,630, 62 genes, copy number 6 (broad region; genes not listed).
- chr1:108,040,263–109,206,781, 37 genes, copy number 6: LINC02785, SLC25A24, AL359258.2, AL359258.3, NBPF4, AL359258.1, SLC25A24P1, NBPF5P, SLC25A24P2, AL390038.1, NBPF6, ST13P21, AL392088.1, FAM102B, HENMT1, PRPF38B, FNDC7, AL591719.2, STXBP3, AL591719.1, AKNAD1, SPATA42, GPSM2, CLCC1, WDR47, BX679664.2, BX679664.3, BX679664.1, RANP5, TAF13, AL356488.3, TMEM167B, SCARNA2, AL356488.2, AL356488.1, C1orf194, ELAPOR1.
- chr6:39,329,990–39,725,408, 1 gene, copy number 6 (within-gene range 4–6): KIF6.
- chr6:39,553,811–54,266,280, 311 genes, copy number 5–9 (broad region; genes not listed).
- chr9:42,566,679–42,569,353, 2 genes, copy number 5: BX088651.4, BX088651.1.
- chr14:106,874,583–106,879,812, 2 genes, copy number 6: IGHV7-81, IGHVIII-82.
- chr15:26,543,546–26,970,385, 6 genes, copy number 6: GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5, TVP23BP1.
- chr15:28,881,667–29,118,315, 2 genes, copy number 9 (within-gene range 1–9): AC174469.1, APBA2.
- chr15:29,120,254–30,883,231, 64 genes, copy number 9 (broad region; genes not listed).
- chr15:30,899,480–30,900,327, 1 gene, copy number 9: AC087481.2.
- chr15:67,521,131–69,461,806, 44 genes, copy number 7–9 (within-gene range 2–9): C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11, CORO2B, CARS1P1, ANP32A, MIR4312, SPESP1, AC087639.1, AC087639.2, AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2, GLCE, AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2.
- chr15:69,564,724–69,565,790, 1 gene, copy number 7: AC100826.1.
- chr15:71,096,952–71,783,383, 1 gene, copy number 10 (within-gene range 2–10): THSD4.
- chr15:71,332,120–72,143,692, 11 genes, copy number 5–10 (within-gene range 1–10): AC064799.2, AC064799.1, AC108861.1, NR2E3, AC104938.1, MYO9A, RNA5SP399, AC022872.1, EIF5A2P1, RNU2-65P, SENP8.
- chr15:75,903,876–76,905,444, 16 genes, copy number 9: FBXO22, NRG4, AC027104.1, TMEM266, AC091100.1, ETFA, Metazoa_SRP, TYRO3P, AC027243.3, ISL2, AC027243.1, AC027243.2, SCAPER, AC090751.1, MIR3713, RN7SKP217.
- chr15:79,559,256–83,207,823, 114 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr15:84,053,113–85,752,901, 66 genes, copy number 5 (broad region; genes not listed).
- chr15:87,325,829–87,703,852, 1 gene, copy number 6 (within-gene range 4–6): AC020687.1.
- chr15:87,576,929–99,716,466, 274 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr17:9,910,606–10,623,886, 11 genes, copy number 5 (within-gene range 3–5): GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2.
- chr17:15,229,773–21,002,276, 327 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:20,999,747–21,000,323, 1 gene, copy number 5 (within-gene range 4–5): AC087393.2.

Autosomal genes at a single copy (total copy number 1): 4,780. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
